Somatic mutation profile of tumor specimen TCGA-S9-A6TS-01A (aliquot TCGA-S9-A6TS-01A-12D-A33T-08) from TCGA case TCGA-S9-A6TS, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 48.9 years (17,857 days).
Specimen TCGA-S9-A6TS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a825a80-82d4-4bb3-a62e-bf645f64f0fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6TS-10A (Blood Derived Normal), aliquot TCGA-S9-A6TS-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55e1c955-e47c-4e4e-bc47-4130a2c91e97

The open-access MAF lists 73 somatic variants for this specimen: 58 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 50, Silent 15, Splice Site 3, Nonsense Mutation 3, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.2117A>G p.N706S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs925822435, CM024554, CM920075, COSV101019594; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 83/186 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 34/43 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 209/616 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs753447548, COSV100623316; called by muse, mutect2, varscan2
- AFF2 | c.3202T>C p.S1068P | Missense Mutation (SNP) | VAF 9/253 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.699); catalogued as COSV53999325; called by muse, mutect2
- ANKRD50 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV101539053; called by muse, mutect2
- ATP7A | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100431750; called by muse, mutect2
- ATRX | c.6683C>T p.T2228I | Missense Mutation (SNP) | VAF 160/386 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as COSV100971492; called by muse, mutect2, varscan2
- C3 | c.2310C>A p.S770R | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99837289; called by muse, mutect2, varscan2
- CAMSAP2 | c.862T>C p.Y288H (on ENST00000236925 / NM_001297707.2; = p.Y277H on NM_203459.3) | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1346979002, COSV99374378; called by muse, mutect2, varscan2
- CCDC58 | c.159T>G p.C53W | Missense Mutation (SNP) | VAF 91/229 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99360588; called by muse, mutect2, varscan2
- CDCP1 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as rs574793682, COSV99944344; called by muse, mutect2, varscan2
- CNGA3 | c.1597G>T p.D533Y | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM148780, COSV99737558; called by muse, mutect2
- CNGA3 | c.1599T>A p.D533E | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99737562; called by muse, mutect2
- DNAH10 | c.5005G>T p.D1669Y (on ENST00000409039; = p.D1608Y on NM_207437.3) | Missense Mutation (SNP) | VAF 138/376 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV101292793, COSV69001140; called by muse, mutect2, varscan2
- ERAL1 | c.1115C>T p.T372I | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.063); catalogued as rs1350224013, COSV99650500; called by muse, mutect2, varscan2
- FAM171A1 | c.2638G>C p.E880Q | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100968604; called by muse, mutect2
- FBXW7 | c.1094G>C p.W365S (on ENST00000281708 / NM_001349798.2; = p.W285S on NM_018315.5) | Missense Mutation (SNP) | VAF 11/336 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55905964, COSV99661179; called by muse, mutect2
- GRIN3A | c.1426C>A p.P476T | Missense Mutation (SNP) | VAF 29/386 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100701834; called by muse, mutect2
- HACE1 | c.2714G>A p.G905D | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99494290; called by muse, mutect2, varscan2
- HNF1B | c.1181A>G p.N394S | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753220832; called by muse, mutect2
- HSPG2 | c.9083C>T p.P3028L | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374881907, COSV101013558; called by muse, mutect2, varscan2
- IL21R | c.946G>T p.V316L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100560612; called by muse, mutect2, varscan2
- JMJD6 | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as rs1406639739, COSV100373320; called by muse, mutect2, varscan2
- KIF2B | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52128836, COSV99276329; called by muse, mutect2
- LHFPL1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 101/228 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767818059, COSV64332935; called by muse, mutect2, varscan2
- LMOD3 | c.578A>G p.D193G | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV101342031; called by muse, mutect2
- LRRC56 | c.462C>A p.S154R | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99530884; called by muse, mutect2, varscan2
- MND1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs750080695, COSV99549132; called by muse, mutect2, varscan2
- MTM1 | c.1313T>C p.F438S | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100080713; called by muse, mutect2
- MUC17 | c.10745T>A p.L3582H | Missense Mutation (SNP) | VAF 148/316 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100075138; called by muse, mutect2, varscan2
- MYBPC1 | c.1972A>G p.R658G (on ENST00000550270 / NM_206820.2; = p.R683G on NM_002465.4) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100638294; called by muse, varscan2
- NAT2 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99674221; called by muse, mutect2, varscan2
- NEU3 | c.489C>G p.Y163* | Nonsense Mutation (SNP) | VAF 67/180 reads (37%) | catalogued as COSV99579783; called by muse, mutect2, varscan2
- OR4S2 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100412697, COSV100412828; called by muse, mutect2, varscan2
- OR52E6 | c.321T>G p.H107Q | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100259568; called by muse, mutect2
- OR8K3 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 127/342 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV100449913; called by muse, mutect2, varscan2
- PGD | c.1333-2A>G p.X445_splice | Splice Site (SNP) | VAF 51/151 reads (34%) | catalogued as COSV99581749; called by muse, mutect2, varscan2
- PLEKHG2 | c.1206G>C p.W402C | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99218143; called by muse, mutect2, varscan2
- RTL9 | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 34/587 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV101511804; called by muse, mutect2
- RUNX1 | c.920G>A p.R307H (on ENST00000344691 / NM_001001890.3; = p.R334H on NM_001754.5) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100278360; called by muse, mutect2, varscan2
- SIAH1 | c.225C>A p.C75* | Nonsense Mutation (SNP) | VAF 52/138 reads (38%) | catalogued as COSV99589543; called by muse, mutect2, varscan2
- SLC39A4 | c.1747G>A p.E583K (on ENST00000301305 / NM_001374839.1; = p.E558K on NM_017767.3) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.852); catalogued as rs1554871935, COSV99433766; called by muse, mutect2, varscan2
- SMARCC1 | c.688T>G p.L230V | Missense Mutation (SNP) | VAF 53/429 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV99593538; called by muse, mutect2, varscan2
- SSX7 | c.185-1G>C p.X62_splice | Splice Site (SNP) | VAF 22/168 reads (13%) | catalogued as COSV99994025; called by muse, mutect2, varscan2
- TENM1 | c.3904G>C p.E1302Q | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100951038; called by muse, varscan2
- TNFAIP8L3 | c.613A>G p.M205V | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100552695; called by muse, mutect2, varscan2
- TRAF4 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99262295; called by muse, mutect2, varscan2
- TRPC5 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV99462826; called by muse, mutect2
- TTN | c.48296G>A p.G16099D (on ENST00000591111; = p.G8675D on NM_003319.4) | Missense Mutation (SNP) | VAF 54/476 reads (11%) | PolyPhen probably damaging (1); catalogued as rs1219250375, COSV100631196; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR64 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs766877773, COSV100844070, COSV63801182; called by muse, mutect2, varscan2
- YME1L1 | c.1415C>G p.P472R (on ENST00000326799 / NM_139312.3; = p.P415R on NM_014263.4) | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV100464271, COSV58761578; called by muse, mutect2
- ZNF99 | c.1716A>T p.K572N | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV101233983; called by muse, mutect2, varscan2
- ZP2 | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 71/206 reads (34%) | catalogued as COSV99559850; called by muse, mutect2, varscan2
- ARID2 | c.2343_2386del p.Q782Pfs*44 | Frame Shift Del (DEL) | VAF 41/106 reads (39%) | called by mutect2, pindel
- SIN3B | c.715_726+9del p.X239_splice | Splice Site (DEL) | VAF 18/115 reads (16%) | called by pindel, varscan2*
- SPDYE5 | c.723G>C p.W241C | Missense Mutation (SNP) | VAF 121/659 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, varscan2
- TCERG1 | c.635A>C p.Q212P | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, varscan2
- AAAS | c.849C>G p.P283= | Silent (SNP) | VAF 14/189 reads (7%) | catalogued as COSV99267132; called by muse, mutect2
- C11orf80 | c.423T>G p.T141= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as COSV100691152; called by muse, mutect2, varscan2
- HSPA14 | c.432G>A p.P144= | Silent (SNP) | VAF 62/158 reads (39%) | catalogued as rs749217062, COSV65685018; called by muse, mutect2, varscan2
- HVCN1 | c.274T>C p.L92= | Silent (SNP) | VAF 51/159 reads (32%) | catalogued as COSV54373706; called by muse, mutect2, varscan2
- IL12RB2 | c.516A>G p.Q172= | Silent (SNP) | VAF 114/304 reads (38%) | catalogued as COSV99255669; called by muse, mutect2, varscan2
- KLF17 | c.642G>A p.P214= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as rs201024510, COSV100955028; called by muse, mutect2, varscan2
- OR10J3 | c.306C>A p.L102= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as COSV100171897; called by muse, mutect2, varscan2
- OR2AG2 | c.600C>T p.Y200= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs1459957291, COSV58454864; called by muse, mutect2, varscan2
- OR4C11 | c.621T>C p.S207= | Silent (SNP) | VAF 98/125 reads (78%) | catalogued as rs1362151877, COSV100155538; called by muse, mutect2, varscan2
- PKHD1L1 | c.8328C>T p.D2776= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as rs376156063; called by muse, mutect2
- SLC25A14 | c.270G>A p.A90= | Silent (SNP) | VAF 33/353 reads (9%) | catalogued as rs772442657, COSV54417230; called by muse, mutect2
- SRGAP2 | c.2853G>A p.S951= (on ENST00000624873 / NM_001170637.4; = p.S952= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs200791583, COSV55334452; called by muse, mutect2, varscan2
- SYNJ1 | c.1398A>T p.S466= | Silent (SNP) | VAF 10/304 reads (3%) | catalogued as COSV100449672; called by muse, mutect2
- TFAP2B | c.1104G>T p.T368= | Silent (SNP) | VAF 39/326 reads (12%) | catalogued as COSV53829206, COSV99540895; called by muse, mutect2, varscan2
- TTLL6 | c.2493C>A p.L831= (on ENST00000393382 / NM_001130918.3; = p.L524= on NM_173623.3) | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV100938235; called by muse, mutect2
